Somatic mutation profile of tumor specimen ALCH-AE9A-TTP1-A (aliquot ALCH-AE9A-TTP1-A-4-0-D-A667-36) from ALCHEMIST case ALCH-AE9A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.5 years (25,391 days).
Specimen ALCH-AE9A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc750d3e-4f96-4e6b-a440-c1e98131e5ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE9A-NB1-A (Blood Derived Normal), aliquot ALCH-AE9A-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed94c652-f442-4a60-b260-7bea3489c988

The open-access MAF lists 80 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Intron 13, Silent 12, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 47/146 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 18/81 reads (22%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALK | c.701C>A p.P234H | Missense Mutation (SNP) | VAF 116/484 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV66563732; called by mutect2, varscan2
- ARHGAP21 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV64544840; called by muse, mutect2, varscan2
- ARHGAP21 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.028); catalogued as COSV64543309; called by muse, mutect2, varscan2
- CLASP1 | c.4096G>A p.A1366T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV55333270; called by muse, mutect2, varscan2
- EYA1 | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 192/543 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs370509332; called by muse, mutect2, varscan2
- FMNL3 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1008158053, COSV53306033, COSV99526152; called by muse, mutect2, varscan2
- GOLGA8T | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748718028, COSV68681827; called by mutect2, varscan2
- KIAA1614 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374751734, COSV62551289; called by muse, mutect2, varscan2
- MUC19 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 25/173 reads (14%) | catalogued as rs777205904; called by muse, mutect2, varscan2
- MYH6 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV62448044, COSV62450210; called by muse, mutect2, varscan2
- NLGN4X | c.1850A>G p.D617G | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99320187; called by muse, mutect2
- NWD1 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs74887865; called by muse, mutect2, varscan2
- OBSCN | c.8609A>G p.Q2870R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs749093875; called by muse, mutect2, varscan2
- OPN1MW | c.832T>C p.C278R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs782219747; called by muse, mutect2, varscan2
- OR4A16 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV59042857; called by muse, mutect2, varscan2
- PCDHA1 | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV65374747; called by muse, mutect2, varscan2
- SLCO1B1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99918570; called by muse, mutect2, varscan2
- TAF4 | c.1894del p.I632* | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as COSV53340996; called by mutect2, pindel, varscan2
- ZFHX4 | c.4943G>A p.G1648E | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV50636410, COSV51505776, COSV99266152; called by muse, mutect2, varscan2
- ZNF225 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749271387; called by muse, mutect2, varscan2
- ADGB | c.4236C>A p.Y1412* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- BNC2 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CASP5 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILP | c.2261T>C p.V754A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL9A1 | c.454T>A p.S152T | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- DMD | c.1813-1G>T p.X605_splice | Splice Site (SNP) | VAF 47/315 reads (15%) | called by muse, mutect2, varscan2
- EIF3E | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ESRP2 | c.1479C>G p.S493R (on ENST00000565858 / NM_001365264.1; = p.S483R on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.216); called by muse, varscan2
- FAM186A | c.6350T>C p.I2117T | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAT2 | c.3301T>A p.S1101T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- FOXM1 | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, varscan2
- FSIP2 | c.3627C>A p.H1209Q | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- H2AC8 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HYKK | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1217 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KIF21B | c.3511C>A p.L1171I | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2
- LILRB1 | c.1592T>C p.L531P (on ENST00000427581; = p.L481P on NM_006669.6) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- LRRC74B | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NRAP | c.2203C>T p.Q735* (on ENST00000359988 / NM_001322945.2; = p.Q700* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- P3H1 | c.1447T>A p.C483S | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, varscan2
- PCLO | c.9924_9931del p.E3309Dfs*8 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- PDHA2 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- PPP1R12B | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RANBP6 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TDRD12 | c.3100G>T p.V1034L (on ENST00000444215; = p.V1039L on NM_001366102.1) | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- TMEM106C | c.496del p.V166Sfs*5 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by mutect2, pindel, varscan2
- TMEM168 | c.683G>T p.C228F | Missense Mutation (SNP) | VAF 182/482 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TTC37 | c.4063A>C p.S1355R | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- WDR35 | c.2585T>C p.I862T (on ENST00000345530 / NM_001006657.2; = p.I851T on NM_020779.4) | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- YTHDF3 | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZNF469 | c.9121G>T p.G3041C (on ENST00000437464; = p.G3069C on NM_001367624.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ZNF77 | c.60G>C p.L20F | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACE2 | c.1749A>C p.P583= | Silent (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- ALG13 | c.2448A>G p.T816= | Silent (SNP) | VAF 108/309 reads (35%) | called by muse, mutect2, varscan2
- DNAH5 | c.9162A>T p.S3054= | Silent (SNP) | VAF 40/230 reads (17%) | called by muse, mutect2, varscan2
- GRM1 | c.471G>A p.A157= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV51169388; called by muse, mutect2, varscan2
- KCND2 | c.996C>A p.T332= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.708C>A p.S236= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV67453368, COSV67499889; called by muse, mutect2, varscan2
- POTEJ | c.1857C>A p.A619= | Silent (SNP) | VAF 76/467 reads (16%) | called by muse, mutect2, varscan2
- PXDN | c.1386C>A p.P462= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs531175244, COSV99412160; called by muse, mutect2, varscan2
- SPG7 | c.228C>T p.N76= | Silent (SNP) | VAF 61/394 reads (15%) | catalogued as rs369989832; ClinVar: likely benign; called by muse, mutect2, varscan2
- VCAN | c.8850C>A p.T2950= | Silent (SNP) | VAF 39/170 reads (23%) | called by muse, mutect2, varscan2
- VN1R2 | c.537C>T p.S179= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- WDR64 | c.399G>A p.V133= | Silent (SNP) | VAF 66/300 reads (22%) | catalogued as rs548066933; called by muse, mutect2, varscan2
- ACTL6A | c.477-757G>T | Intron (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- ASTN1 | c.2482+50T>C | Intron (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- DACH2 | c.488+35173C>A | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- FMR1 | c.*1210_*1214del | 3'UTR (DEL) | VAF 98/315 reads (31%) | called by pindel, varscan2
- HLA-DQA1 | c.613+13T>A | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2
- KALRN | c.5176+21750G>T | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52256791; called by muse, varscan2
- MARCHF1 | c.242+877A>C | Intron (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+800G>A | Intron (SNP) | VAF 25/93 reads (27%) | called by muse, varscan2
- MARCHF1 | c.242+744T>A | Intron (SNP) | VAF 41/202 reads (20%) | called by muse, varscan2
- MYB | c.948+519A>T | Intron (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- PPP1R8 | c.117+1612A>G | Intron (SNP) | VAF 37/200 reads (19%) | catalogued as rs947288315; called by muse, mutect2, varscan2
- RIMS2 | c.698+52974C>A | Intron (SNP) | VAF 205/575 reads (36%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13372T>C | Intron (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- TTC6 | c.1201-4009A>T | Intron (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
